Gene-level copy-number profile of tumor specimen TCGA-2H-A9GI-01A from TCGA case TCGA-2H-A9GI, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.7 years (25,097 days).
Specimen TCGA-2H-A9GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.10fcbdc5-98d0-4ce1-ac45-989853226e96.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GI-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0fdb4a5e-772d-4bb1-a480-c82be3a45c9d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 2,827; copy number 2: 24,094; copy number 3: 26,827; copy number 4: 4,263; copy number 5: 149; copy number 6: 1,288; copy number 7: 37; copy number 8: 24; copy number 9: 9; copy number 10: 12; copy number 14: 45; copy number 20: 12; copy number 25: 17; copy number 26: 105.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GI-01A-11D-A37B-01): tumor purity 0.6, ploidy 2.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:136,118,675–136,395,471, 1 gene (within-gene range 0–1): AC018680.1.
- chr4:136,355,110–136,553,739, 2 genes: TERF1P3, AC093875.1.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr9:19,507,452–25,678,440, 94 genes (within-gene range 0–2) (broad region; genes not listed).
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 261 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,160,021–167,407,874, 16 genes, copy number 8 (within-gene range 6–8): MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX.
- chr3:168,094,049–173,336,965, 94 genes, copy number 7–20 (broad region; genes not listed).
- chr3:173,644,231–173,644,711, 1 gene, copy number 10: AC092967.1.
- chr4:163,093,574–163,382,516, 7 genes, copy number 9: MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12.
- chr10:112,671,812–113,167,678, 8 genes, copy number 8: AL139120.1, AL158212.5, AL158212.3, AL158212.4, AL158212.1, TCF7L2, AL158212.2, RPS15AP30.
- chr13:42,781,550–42,814,897, 2 genes, copy number 9: FAM216B, LINC01050.
- chr17:39,546,104–39,877,896, 17 genes, copy number 25: RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:40,388,525–41,812,604, 105 genes, copy number 26 (within-gene range 3–26) (broad region; genes not listed).
- chr17:49,494,223–49,789,180, 10 genes, copy number 10: AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A.
- chr17:49,795,343–49,795,669, 1 gene, copy number 10: SRP14P3.

Autosomal genes at a single copy (total copy number 1): 1,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
